Gene-level copy-number profile of tumor specimen TCGA-EA-A43B-01A from TCGA case TCGA-EA-A43B, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 43.5 years (15,871 days).
Specimen TCGA-EA-A43B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.5ce65ecb-cf89-4039-97be-3b5c879871aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A43B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f389642e-55da-461b-bc0e-23b8efe15931

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 212; copy number 2: 6,593; copy number 3: 10,100; copy number 4: 21,834; copy number 5: 12,024; copy number 6: 6,742; copy number 7: 283; copy number 8: 759; copy number 10: 1,136; copy number 11: 16; copy number 15: 41; copy number 24: 5; copy number 34: 7; copy number 37: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A43B-01A-81D-A242-01): tumor purity 0.38, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,581,357–213,021,545, 7 genes (within-gene range 0–2): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,265 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–38,154,624, 1,135 genes, copy number 10 (broad region; genes not listed).
- chr6:38,207,274–38,207,345, 1 gene, copy number 10: AL033518.1.
- chr6:72,316,599–74,850,484, 45 genes, copy number 11–15: AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2, AL356473.1.
- chr11:97,878,475–104,682,581, 77 genes, copy number 11–37 (broad region; genes not listed).
- chr11:105,041,326–105,531,697, 7 genes, copy number 34 (within-gene range 1–34): CARD16, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1.

Autosomal genes at a single copy (total copy number 1): 212. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
